Somatic mutation profile of tumor specimen TCGA-F7-A50I-01A (aliquot TCGA-F7-A50I-01A-11D-A28R-08) from TCGA case TCGA-F7-A50I, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 72.2 years (26,373 days).
Specimen TCGA-F7-A50I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f612b2-3296-44d7-9429-cbfea66067a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A50I-10A (Blood Derived Normal), aliquot TCGA-F7-A50I-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c976a8c3-3fc1-4e9f-a09c-f652cca06c7d

The open-access MAF lists 149 somatic variants for this specimen: 112 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 35, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 4, Splice Site 3, RNA 1, Nonstop Mutation 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1573T>A p.F525I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99225582; called by muse, mutect2
- ACTL6A | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV66998722; called by muse, mutect2, varscan2
- ADD3 | c.1873C>T p.P625S (on ENST00000356080 / NM_001320591.2; = p.P593S on NM_001121.4) | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV99523271; called by muse, mutect2
- ADGRB1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758185771, COSV60100700; called by muse, mutect2, varscan2
- ADGRF5 | c.3449C>G p.T1150S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99345175; called by muse, mutect2
- ADGRL4 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100875753; called by muse, mutect2
- AKR1B10 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1415157276, COSV100610162; called by muse, mutect2
- APOB | c.8013G>T p.K2671N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV51935745, COSV99264561; called by muse, mutect2, varscan2
- ARPP21 | c.2320C>G p.Q774E | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51802133; called by muse, mutect2, varscan2
- ASTE1 | c.1507A>T p.S503C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53909730, COSV99393716; called by muse, mutect2, varscan2
- ATP10B | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs374878756; called by muse, mutect2, varscan2
- ATP13A5 | c.2983G>T p.V995L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100664906; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- B3GNT5 | c.157A>C p.N53H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100191819; called by muse, mutect2, varscan2
- C6 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99666798; called by muse, mutect2, varscan2
- CAPZA1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as COSV54144335, COSV99582998; called by muse, mutect2, varscan2
- CCDC138 | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99718938; called by muse, mutect2, varscan2
- CCDC50 | c.1076A>T p.Q359L (on ENST00000392455 / NM_178335.3; = p.Q183L on NM_174908.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101165265; called by muse, mutect2, varscan2
- CFH | c.3250T>C p.F1084L | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV100809155; called by muse, mutect2, varscan2
- CNBD1 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101582180; called by muse, mutect2, varscan2
- CNNM2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100881678; called by muse, mutect2
- CNOT1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100408802; called by muse, mutect2, varscan2
- COL1A1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.714); catalogued as COSV99866745; called by muse, mutect2, varscan2
- COL7A1 | c.6618+1G>T p.X2206_splice | Splice Site (SNP) | VAF 32/123 reads (26%) | catalogued as COSV100095479, COSV60405578; called by muse, mutect2, varscan2
- CSMD2 | c.2579T>C p.I860T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV99587648; called by muse, mutect2, varscan2
- CTSA | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99509742; called by muse, mutect2
- CUL4A | c.680A>G p.Y227C (on ENST00000375440 / NM_001008895.4; = p.Y127C on NM_003589.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417110; called by muse, mutect2, varscan2
- CYTIP | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs200094703, COSV51636282, COSV99938683; called by muse, mutect2, varscan2
- DDHD1 | c.706G>C p.E236Q (on ENST00000323669; = p.E433Q on NM_030637.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV100079268; called by muse, mutect2
- DDX24 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100427869; called by muse, mutect2, varscan2
- DENND3 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99370568; called by muse, mutect2
- DGAT2L6 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV100283927; called by muse, mutect2, varscan2
- DISP3 | c.2440G>C p.V814L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99607883; called by muse, mutect2, varscan2
- DMD | c.7717C>A p.Q2573K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.138); catalogued as CM165337, COSV100626462; called by muse, mutect2, varscan2
- EFCAB6 | c.1966G>A p.V656M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs762612939, COSV53071646; called by muse, mutect2, varscan2
- EGR1 | c.1178A>T p.E393V | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99525368; called by muse, mutect2, varscan2
- EPB41L2 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 57/326 reads (17%) | catalogued as COSV100440418; called by muse, mutect2, varscan2
- FAT1 | c.4089dup p.T1364Yfs*8 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs1279779959; called by mutect2, pindel, varscan2
- FBN2 | c.2664G>C p.L888F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99324349, COSV99325964; called by muse, mutect2, varscan2
- FMN2 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100144107, COSV60415863, COSV60417057; called by muse, mutect2, varscan2
- FMNL3 | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764731297, COSV53308087; called by muse, mutect2, varscan2
- GMNN | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs150391376; called by muse, mutect2, varscan2
- GPR179 | c.6061C>T p.P2021S (on ENST00000621958; = p.P2020S on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as rs751498856; called by muse, mutect2
- HEATR1 | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100857554; called by muse, mutect2
- HIVEP3 | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99911965; called by muse, mutect2, varscan2
- HNF4G | c.1028A>G p.H343R (on ENST00000354370 / NM_001330561.2; = p.H390R on NM_004133.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs1160048541, COSV62967958; called by muse, mutect2, varscan2
- HSD17B2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99556515, COSV99556844; called by muse, mutect2, varscan2
- IMPG1 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.08); catalogued as COSV100774811; called by muse, mutect2
- INPP4B | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV99523590; called by muse, mutect2
- IP6K3 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs369669636; called by muse, mutect2, varscan2
- IREB2 | c.2168T>G p.F723C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99359180; called by muse, mutect2, varscan2
- ITPRIPL1 | c.22T>C p.S8P (on ENST00000439118 / NM_001008949.3; = p.S16P on NM_178495.6) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1443518155, COSV100742169; called by muse, mutect2, varscan2
- JUP | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100159420; called by muse, mutect2, varscan2
- KCNK18 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.36); catalogued as COSV100572006; called by muse, mutect2, varscan2
- LOXL1 | c.1559G>T p.W520L | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99985241; called by muse, mutect2, varscan2
- LRGUK | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603899; called by muse, mutect2
- MAN2A1 | c.2043A>T p.K681N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99810702; called by muse, mutect2, varscan2
- MFSD8 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV99614254; called by muse, mutect2, varscan2
- MYH2 | c.2042C>G p.P681R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99819646, COSV99820241; called by muse, mutect2, varscan2
- NAV3 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99888513; called by muse, mutect2, varscan2
- NKIRAS1 | c.350dup p.L118Ifs*9 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | catalogued as rs1336512336; called by mutect2, pindel, varscan2
- NOTCH1 | c.6139C>T p.L2047F | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486419; called by muse, mutect2, varscan2
- OMP | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs782797737, COSV99581930; called by muse, mutect2, varscan2
- OR2A25 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101376364; called by muse, mutect2
- PAPPA2 | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as rs571516637, COSV100866653; called by muse, mutect2
- PAPPA2 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100866654; called by muse, mutect2, varscan2
- PARD3 | c.4018G>A p.A1340T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs756860827, COSV100631390; called by muse, mutect2, varscan2
- PCDH18 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100787155; called by mutect2, varscan2
- PCDHAC1 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV53839791; called by muse, mutect2, varscan2
- PHRF1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs1295513258, COSV99199721; called by muse, mutect2, varscan2
- PON3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55700030, COSV99672346; called by muse, mutect2, varscan2
- POSTN | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123282; called by muse, mutect2, varscan2
- QKI | c.1024T>C p.*342Qext*5 | Nonstop Mutation (SNP) | VAF 90/392 reads (23%) | catalogued as COSV99274617; called by muse, mutect2, varscan2
- RASSF2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1475425824, COSV101040684, COSV65083471; called by muse, mutect2, varscan2
- RGL2 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV101442491; called by muse, mutect2, varscan2
- RNF43 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100089974; called by muse, mutect2, varscan2
- RUNX2 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs114654066, COSV100767218, COSV100767563; called by muse, mutect2, varscan2
- RYR1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs773794000, COSV62098661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A6 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs758855513, COSV100692015; called by muse, mutect2, varscan2
- SNED1 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs367564091; called by muse, mutect2
- SOBP | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV57997184; called by muse, mutect2, varscan2
- SPHK2 | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV99709247; called by muse, mutect2, varscan2
- SPTB | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67631124; called by muse, mutect2
- ST18 | c.163A>T p.K55* | Nonsense Mutation (SNP) | VAF 16/187 reads (9%) | catalogued as COSV99388874; called by muse, mutect2
- STX17 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99407909; called by muse, mutect2, varscan2
- TAF1B | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99721949; called by muse, mutect2, varscan2
- TIGIT | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67329181; called by muse, mutect2, varscan2
- TIMM13 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.268); catalogued as COSV99295922; called by muse, mutect2, varscan2
- TJP2 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99600851, COSV99601485; called by muse, mutect2, varscan2
- TLE4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV54629902; called by muse, mutect2
- TNS1 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99410176; called by muse, mutect2, varscan2
- TSHR | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99991395; called by muse, mutect2, varscan2
- UBA3 | c.1250C>A p.S417* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100734643, COSV62741522; called by muse, mutect2, varscan2
- UBA6 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1479242276, COSV100451617; called by muse, mutect2
- XPO5 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99540624; called by muse, mutect2, varscan2
- ZDHHC12 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.606); catalogued as COSV52577644, COSV99403415; called by muse, mutect2, varscan2
- ZMIZ1 | c.2287-2A>G p.X763_splice | Splice Site (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100565996; called by muse, mutect2, varscan2
- ZNF174 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV99237289; called by muse, mutect2, varscan2
- ZNF354C | c.1599C>A p.F533L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100203546, COSV59607212; called by muse, mutect2, varscan2
- ZNF470 | c.1003A>C p.T335P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs763736722, COSV100401149; called by muse, mutect2, varscan2
- ZNF619 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); catalogued as rs780921812, COSV100123116; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2715G>T p.Q905H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2
- DNAJB2 | c.321del p.F107Lfs*94 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- FCGBP | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- MTERF4 | c.769del p.S257Hfs*2 | Frame Shift Del (DEL) | VAF 17/120 reads (14%) | called by mutect2, pindel, varscan2
- PICALM | c.1724del p.G575Dfs*23 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- SLF2 | c.2437_2438dup p.M813Ifs*2 | Frame Shift Ins (INS) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- SNTG1 | c.1038+2_1038+5dup | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel
- SUPT20HL1 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB39 | c.1596_1606del p.L533Pfs*31 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ACAD10 | c.97C>A p.R33= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs148699934, COSV100563972; called by muse, mutect2, varscan2
- ALDH1A2 | c.1137G>C p.V379= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs141958697; called by muse, mutect2, varscan2
- APOBEC3G | c.792C>T p.D264= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1423296071, COSV101349053, COSV68470867; called by muse, mutect2
- CHEK2 | c.843C>T p.F281= (on ENST00000382580 / NM_001005735.2; = p.F238= on NM_007194.4) | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs864622322, COSV60418409; ClinVar: likely benign; called by muse, mutect2
- COL4A3 | c.4221A>G p.E1407= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV101170117; called by muse, mutect2
- CYP17A1 | c.1161C>T p.D387= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100882086; called by muse, mutect2, varscan2
- DDC | c.261G>A p.P87= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs200437940, COSV63563685; called by muse, mutect2, varscan2
- DNAH5 | c.7212T>C p.D2404= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs876657454, COSV99447000; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DNALI1 | c.162A>G p.K54= (on ENST00000296218; = p.K32= on NM_003462.5) | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as COSV99953048; called by muse, mutect2
- EBF3 | c.510T>C p.C170= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100799110; called by muse, mutect2
- EXOC5 | c.2097A>G p.R699= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as COSV100567023; called by muse, mutect2, varscan2
- FGA | c.738A>T p.P246= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100120190; called by muse, mutect2, varscan2
- GALNT14 | c.24G>T p.L8= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100204345; called by muse, mutect2
- GPAT2 | c.1707G>A p.P569= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs751676628; called by mutect2, varscan2
- KLHL1 | c.2226G>A p.V742= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100917116, COSV64773050; called by muse, mutect2, varscan2
- LARP4B | c.1089G>T p.T363= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100295184; called by muse, mutect2, varscan2
- LMTK2 | c.4467G>T p.S1489= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV51990452, COSV99806365; called by muse, mutect2, varscan2
- LRRN1 | c.543T>A p.V181= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100076158; called by muse, mutect2, varscan2
- MMAA | c.699A>T p.G233= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99849709; called by muse, mutect2, varscan2
- MUC16 | c.30399G>T p.V10133= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV101198972; called by muse, mutect2, varscan2
- MYH13 | c.3744C>T p.N1248= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99353026; called by muse, mutect2, varscan2
- NCKAP1L | c.1710G>T p.L570= | Silent (SNP) | VAF 41/251 reads (16%) | catalogued as COSV99514749; called by muse, mutect2, varscan2
- OLFML2B | c.1686C>T p.S562= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV99668209; called by muse, mutect2
- PCSK6 | c.1446C>T p.D482= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1454206355, COSV100083256, COSV59338575; called by muse, mutect2, varscan2
- RREB1 | c.2232G>T p.L744= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV100619233; called by muse, mutect2, varscan2
- SIM1 | c.1599G>A p.V533= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99492142; called by muse, mutect2, varscan2
- STK38L | c.801G>A p.R267= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101198743; called by muse, mutect2, varscan2
- TAF1L | c.3990T>C p.D1330= | Silent (SNP) | VAF 23/308 reads (7%) | catalogued as COSV99644348; called by muse, mutect2
- TDP1 | c.894G>A p.L298= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as COSV100187674; called by muse, mutect2, varscan2
- TDRD6 | c.1170G>A p.R390= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV100287356; called by muse, mutect2, varscan2
- TRIP6 | c.489G>A p.P163= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs745950801, COSV99307640; called by muse, mutect2, varscan2
- TRPA1 | c.1866A>T p.P622= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100083602; called by muse, mutect2, varscan2
- TSPY2 | c.501C>A p.P167= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100289172; called by muse, mutect2, varscan2
- UGT3A1 | c.921T>C p.H307= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99954494; called by muse, mutect2, varscan2
- ZBTB14 | c.426T>C p.S142= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs1426790815, COSV100813425; called by muse, mutect2, varscan2
- LPAL2 | n.169C>T | RNA (SNP) | VAF 66/265 reads (25%) | called by muse, mutect2, varscan2
- RBCK1 | c.168-188A>G | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
